Surgical pathology report (de-identified scan), TCGA case TCGA-SR-A6MQ, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Tufts Medical Center, specimen TCGA-SR-A6MQ-01A (Primary Tumor).

[page 1 of 2]
Specimen:	Patient:	
Procedure:	Medical Record #:	Account #:
Accessioned:	DOB/Age/Sex:	(Age: F
Reported:	Location/Client:	
Submitting Phys:		

Surgical Pathology Report

Final Diagnosis

EXTRA-ADRENAL PHEOCHROMOCYTOMA, EXCISION:

- PARAGANGLIOMA, 4.2 CM GREATEST DIMENSION.
- THERE IS A MICROSCOPIC FOCUS OF TRANSCAPSULAR INVASION INTO ADJACENT FAT, WITH TUMOR CELLS EXTENDING FOCALLY TO THE INKED SURFACE (BEST SEEN IN A8 SECTIONS STAINED IMMUNOHISTOCHEMICALLY FOR CHROMOGRANIN A OR SYNAPTOPHYSIN).
- THERE IS NO EVIDENCE OF VASCULAR INVASION OR NECROSIS. MITOSES ARE EXTREMELY RARE. KI-67 LABELING INDEX IS LOW (APPROXIMATELY 2% IN AREAS OF HIGHEST LABELING).
- OCCASIONAL SMALL AREAS OF NEURON-LIKE DIFFERENTIATION ARE PRESENT. THESE HAVE NO CLINICAL SIGNIFICANCE.
- IMMUNOHISTOCHEMICAL STAIN FOR S-100 SHOWS VARYING NUMBERS OF SUSTENTACULAR CELLS THROUGHOUT THE TUMOR.

***Report Electronically Signed By.

**

This certifies that the pathologist named above has personally conducted a microscopic examination (or gross examination only, where stated) of the described specimen(s) and has rendered or confirmed the final diagnosis(es).

Intra-Operative Consultation with Frozen Section

A-FS) FROZEN SECTION, EXTRA-ADRENAL PHEOCHROMOCYTOMA, EXCISION:

- PARAGANGLIOMA.

Clinical History

Paraganglioma adrenal pheochromocytoma

Pre-Operative Diagnosis

{Not Provided}

Post-Operative Diagnosis

{Not Provided}

Gross Description

A. EXTRA ADRENAL PHEOCHROMOCYTOMA (FRESH): The specimen, labeled with the patient's name and accession number, is an encapsulated mass of dark red-purple and tan-red tissue measuring 4.2 x 3.3 x 1.2 cm. There is no gross evidence of capsular invasion. The specimen is inked blue. A representative section is submitted to include both the dark-red and tan-red regions for frozen section. The frozen section residue is submitted in cassette A1. Samples are frozen for additional studies. Remainder of the specimen is submitted in cassettes A2-5, with the tan-red region submitted in A2.

Immunohistochemical staining performed in this case may involve reagents labeled as analyte specific reagents. For these cases: This test was developed and its performance characteristics determined by Department of Pathology. It has not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical

[page 2 of 2]
purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

Department of Pathology
- End of Report -

Page 2 of 2
Printed:

Source: NCI Genomic Data Commons file c3c01b7d-867e-4038-9d4e-23ee2248eb72 (TCGA-SR-A6MQ.A8D3E15B-0613-4896-B03D-4F427629845A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).